Somatic mutation profile of tumor specimen TCGA-A6-5666-01A (aliquot TCGA-A6-5666-01A-01D-1650-10) from TCGA case TCGA-A6-5666, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 78.1 years (28,514 days).
Specimen TCGA-A6-5666-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76ab2081-4e8c-4bf5-b469-277fbfece18c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5666-10A (Blood Derived Normal), aliquot TCGA-A6-5666-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efada147-11ef-4e36-b4a0-dc4a013b6b64

The open-access MAF lists 96 somatic variants for this specimen: 76 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 18, Nonsense Mutation 4, Frame Shift Ins 2, Frame Shift Del 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 81/220 reads (37%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555038090, COSV63293359; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 78/196 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 59/172 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHRR | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs763403491, COSV100326692; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6322A>G p.T2108A | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51860144; called by muse, mutect2, varscan2
- AREL1 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV62667971; called by muse, mutect2, varscan2
- ASAH1 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 81/127 reads (64%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100026028, COSV50501754; called by muse, mutect2, varscan2
- BRPF3 | c.1616A>G p.D539G | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs777815971, COSV60210472; called by muse, mutect2, varscan2
- BSN | c.8581G>A p.E2861K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs755443229, COSV56529322; called by muse, mutect2, varscan2
- C1orf87 | c.1063C>A p.L355M | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV64596070, COSV64599207; called by muse, mutect2, varscan2
- CACNA1E | c.3253G>A p.V1085M | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs768308084, COSV62433415; called by muse, mutect2, varscan2
- CAPN9 | c.1722C>T p.D574= | Splice Region (SNP) | VAF 56/156 reads (36%) | catalogued as rs995056082, COSV55236778; called by muse, mutect2, varscan2
- CAPS2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs373505414, COSV60824815; called by muse, mutect2, varscan2
- CATSPER1 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV56413966; called by muse, mutect2, varscan2
- CENPI | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 191/443 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs761693180, COSV54500533; called by muse, mutect2, varscan2
- CHD6 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 30/460 reads (7%) | catalogued as rs1569094685, COSV100497814; called by muse, mutect2
- CLVS1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs368485692; called by muse, mutect2, varscan2
- COL4A1 | c.1477C>A p.Q493K | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT tolerated (0.9); PolyPhen benign (0.254); catalogued as COSV65432862; called by muse, mutect2, varscan2
- COL5A1 | c.4753C>T p.R1585W | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs546865410, COSV65675928; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE9 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.102); catalogued as COSV56070130; called by muse, mutect2, varscan2
- DNMT3B | c.1633C>T p.R545C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs372550911; called by muse, mutect2, varscan2
- DSCAM | c.4534G>C p.E1512Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs767997820, COSV68020067, COSV68031003; called by muse, mutect2, varscan2
- EEF1A1 | c.756T>G p.D252E | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as COSV58550907; called by muse, mutect2, varscan2
- EFEMP2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); catalogued as rs1378442215, COSV57260818, COSV57261686; called by muse, mutect2, varscan2
- EPG5 | c.2627G>T p.R876L | Missense Mutation (SNP) | VAF 179/228 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as COSV56353111, COSV56356854; called by muse, mutect2, varscan2
- FBXO40 | c.2122G>A p.V708I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs377351705; called by muse, mutect2, varscan2
- FDPS | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV63115616; called by muse, mutect2, varscan2
- FGD6 | c.2096A>T p.E699V | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.253); catalogued as COSV59697657; called by muse, mutect2, varscan2
- FGFR2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs141724446; called by muse, mutect2, varscan2
- GPR158 | c.2523G>T p.E841D | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.038); catalogued as COSV66284609; called by muse, mutect2, varscan2
- GRM5 | c.3281G>T p.C1094F (on ENST00000305447 / NM_001143831.2; = p.C1062F on NM_000842.4) | Missense Mutation (SNP) | VAF 64/133 reads (48%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.603); catalogued as COSV59633154; called by muse, mutect2, varscan2
- GUCY1A1 | c.1936T>C p.F646L | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV56657203; called by muse, mutect2, varscan2
- HTR2C | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.268); catalogued as rs782100644, COSV52226405; called by muse, mutect2, varscan2
- IL1RAPL2 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 151/176 reads (86%) | catalogued as COSV61186643; called by muse, mutect2, varscan2
- JPH2 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.7); catalogued as rs747722861, COSV65902177; called by muse, mutect2, varscan2
- KCNH5 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765878799, COSV59774024; called by muse, mutect2, varscan2
- KLF5 | c.919T>G p.S307A | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV66615648; called by muse, mutect2, varscan2
- KMT2C | c.14416C>T p.R4806* | Nonsense Mutation (SNP) | VAF 152/287 reads (53%) | catalogued as COSV51308724, COSV51476088; called by muse, mutect2, varscan2
- LARP4B | c.51_52del p.R17Sfs*35 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | catalogued as rs1346170695; called by pindel, varscan2
- LCE2B | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.015); catalogued as COSV64228120; called by muse, mutect2, varscan2
- LRATD1 | c.482T>C p.I161T | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99707012; called by muse, mutect2, varscan2
- LRP2 | c.2328A>C p.E776D | Missense Mutation (SNP) | VAF 151/173 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99786757; called by muse, mutect2, varscan2
- LRRC41 | c.1340G>T p.C447F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs1270131430, COSV58442739; called by muse, mutect2, varscan2
- LRRC8B | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58376960; called by muse, mutect2, varscan2
- NKPD1 | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.291); catalogued as COSV58730513; called by muse, mutect2, varscan2
- NLRP13 | c.1518G>T p.E506D | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.072); catalogued as COSV61622344; called by muse, mutect2, varscan2
- NLRP9 | c.791dup p.M265Dfs*36 | Frame Shift Ins (INS) | VAF 36/103 reads (35%) | catalogued as rs745704129; called by mutect2, varscan2
- NRCAM | c.2320G>A p.E774K (on ENST00000379028 / NM_001371124.1; = p.E758K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs774089913, COSV61033000; called by muse, mutect2, varscan2
- OR51F1 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV58581059; called by muse, mutect2, varscan2
- PDE4A | c.2578A>G p.S860G (on ENST00000380702 / NM_001111307.2; = p.S621G on NM_006202.3) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.026); catalogued as rs777713898, COSV53363805; called by muse, mutect2
- PEG3 | c.2702G>A p.R901H | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs560114002, COSV55625491; called by muse, mutect2, varscan2
- POU3F3 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 82/113 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.203); catalogued as COSV63722546; called by muse, mutect2, varscan2
- PRSS37 | c.222C>A p.D74E | Missense Mutation (SNP) | VAF 158/437 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.281); catalogued as COSV63339074, COSV63340270; called by muse, mutect2, varscan2
- RAB27B | c.168A>C p.Q56H | Missense Mutation (SNP) | VAF 57/72 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV50496696; called by muse, mutect2
- RD3 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65362980; called by muse, mutect2, varscan2
- RNF44 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs368342651; called by muse, mutect2, varscan2
- SALL4 | c.2620C>T p.R874W | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.891); catalogued as rs141341062; called by muse, mutect2, varscan2
- SCAF8 | c.2623A>G p.N875D | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.307); catalogued as rs766420699, COSV65794164; called by muse, mutect2, varscan2
- SEMA3A | c.2143C>A p.L715I | Missense Mutation (SNP) | VAF 229/510 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV54890945; called by muse, mutect2, varscan2
- SHANK3 | c.2219G>T p.R740L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV53188868, COSV53192053; called by muse, mutect2, varscan2
- SLC25A48 | c.458C>T p.A153V (on ENST00000650267; = p.A99V on NM_001349335.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs377170548; called by muse, mutect2, varscan2
- SLIT1 | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.996); catalogued as rs1268863455, COSV56600812; called by muse, mutect2, varscan2
- SMARCD2 | c.1466del p.P489Lfs*19 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as COSV56738330; called by mutect2, pindel, varscan2
- SMCR8 | c.2404C>T p.R802C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368462355; called by muse, mutect2, varscan2
- TRIM56 | c.1864A>T p.T622S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.935); catalogued as COSV60161727; called by muse, mutect2, varscan2
- TRPM7 | c.5167A>G p.M1723V | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV57913279; called by muse, mutect2, varscan2
- TRPV6 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 184/354 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as rs375523215; called by muse, mutect2, varscan2
- WIPI2 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1290452597, COSV56589141; called by muse, mutect2, varscan2
- ZFP36L2 | c.305dup p.E103Gfs*23 | Frame Shift Ins (INS) | VAF 21/28 reads (75%) | catalogued as COSV56697149; called by mutect2, pindel, varscan2
- ZFR2 | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs752835584, COSV53604115; called by muse, mutect2, varscan2
- ZMYND11 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); catalogued as rs751729106, COSV59082667; called by muse, mutect2, varscan2
- ZNF383 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs146239366; called by muse, mutect2, varscan2
- ZNF536 | c.2729A>G p.N910S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV62835835; called by muse, mutect2, varscan2
- ZSCAN18 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53732302, COSV99559132; called by muse, mutect2, varscan2
- CASS4 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- ACTN1 | c.2586G>A p.A862= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV51998742; called by muse, mutect2
- ANK2 | c.11523G>A p.P3841= | Silent (SNP) | VAF 47/101 reads (47%) | catalogued as rs143290935; called by muse, mutect2, varscan2
- BRINP3 | c.1335C>T p.D445= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as rs746938927, COSV66514992; called by muse, varscan2
- DGKB | c.1803C>A p.I601= | Silent (SNP) | VAF 294/670 reads (44%) | catalogued as COSV51824318; called by muse, varscan2
- GCAT | c.627C>T p.G209= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs746358358, COSV50650566; called by muse, mutect2, varscan2
- GLI2 | c.3288G>A p.A1096= (on ENST00000361492 / NM_001374353.1; = p.A1113= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV58044011; called by muse, mutect2, varscan2
- KCNH5 | c.2289G>A p.T763= | Silent (SNP) | VAF 106/265 reads (40%) | catalogued as rs1286363254, COSV100528476, COSV59780498; called by muse, mutect2, varscan2
- MAP2 | c.3501C>A p.V1167= | Silent (SNP) | VAF 172/203 reads (85%) | catalogued as COSV52310656; called by muse, mutect2, varscan2
- MOBP | c.126G>T p.R42= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV100215468, COSV60654104; called by muse, mutect2, varscan2
- NLRP4 | c.1815C>T p.S605= | Silent (SNP) | VAF 82/201 reads (41%) | catalogued as rs143787739; called by muse, varscan2
- OR2T2 | c.759C>T p.Y253= | Silent (SNP) | VAF 61/220 reads (28%) | catalogued as rs763553843, COSV61618280; called by muse, varscan2
- PCDH10 | c.2487C>T p.S829= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV52091098; called by muse, mutect2
- PNLDC1 | c.945C>T p.V315= | Silent (SNP) | VAF 118/286 reads (41%) | catalogued as COSV51708546; called by muse, mutect2, varscan2
- SNTG2 | c.1206C>T p.N402= | Silent (SNP) | VAF 144/171 reads (84%) | catalogued as rs371202003; called by muse, mutect2, varscan2
- SYNE1 | c.14172G>A p.A4724= (on ENST00000367255 / NM_182961.4; = p.A4653= on NM_033071.3) | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs200419328, COSV54965826, COSV55069486; called by muse, mutect2, varscan2
- VTN | c.483C>T p.F161= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs782463783, COSV56875202; called by muse, mutect2, varscan2
- ZIM2 | c.1191G>A p.A397= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs143841099, COSV55649915; called by muse, mutect2, varscan2
- ZNF546 | c.903C>T p.Y301= | Silent (SNP) | VAF 63/175 reads (36%) | catalogued as rs759476122, COSV61259728; called by muse, mutect2, varscan2
- BIRC8 | n.1456G>T | RNA (SNP) | VAF 17/504 reads (3%) | catalogued as COSV70346642, COSV70347389; called by muse, mutect2
- MIR193A | n.32G>A | RNA (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
